Surgical pathology report (de-identified scan), TCGA case TCGA-06-A7TL, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A7TL-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: (Age:) Location: Received:
Gender: F Acct: Reported:
Physician(s):
Phy Location:

Clinical History

-year-old woman has experienced "walking" seizures for about . On imaging, there is a heterogeneously enhancing large intra axial lesion involving left fronto-temporal lobes and insula, with mass effect.

Operative Diagnoses

Brain tumor.

Operation / Specimen

A: Brain, nonenhancing tumor, biopsy
B: Brain, right insular tumor, excision biopsy

Pathologic Diagnosis

A, B. Brain, right frontotemporal and insular tumor, excision:

1. Glioblastoma, WHO grade 4
2. Negative for co-deletion of chromosomal arms 1p and 19q
3. Positive for mutant IDH1-R132H protein by immunostain

See comment.

Comment

The portions of cerebrum are diffusely infiltrated and focally effaced by a glial neoplastic proliferation. In part A, the non-enhancing tumor is diffusely infiltrative, and sparsely to moderately cellular. In part B, the tumor tends to be more solid, with hypercellular areas. The infiltrating cells have oval to elongated and spindle-shaped nuclei. The immunostain for the mutant IDH1-R132H protein is diffusely positive. There are foci with brisk mitotic activity and the Ki-67/ MIB-1 proliferation index is up to approximately 13% in the most active areas. Foci of microvascular proliferation are also identified, highlighted by the CD34 immunostain and in negative relief by the GFAP immunostain. There is no tumor necrosis seen in these sections. Overall, this high histological grade diffuse glioma is most consistent with glioblastoma, WHO grade 4.

Electronically Signed Out

Consultant: MD, Senior Staff Pathologist
MD, Senior Staff Pathologist

Procedures/Addenda

MGMT Promoter Methylation

Surgical Pathology

Page 2 of 3

Date Ordered: Date Reported:

Interpretation

LOW POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (B1).

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

ICD-O-3
Glioblastoma multiforme
09440/3
Site R Brain, overlapping
lesion C71.2
9/26/13

[page 2 of 3]
from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: **Date Reported:**

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S468, D1S552, D1S1612, D1S496, D19S219 and D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin block (A1). DNA extracted from a corresponding blood specimen was used as a normal reference control.

H and E slide was examined and tumor DNA was enriched by microdissection

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3

markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and

D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and

D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26

nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of

interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or

otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the

typical finding in oligodendrogliomas with 1p and 19q deletion.

Surgical Pathology

Page 3 of 3

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

[page 3 of 3]
provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

Electronically Signed Out

M.D., Senior Staff Pathologist

Intra-Operative Consultation

A. Brain, nonenhancing tumor, biopsy: Gliofibrillary neoplasm, diffusely infiltrating, C/W glioma (astrocytic? High

grade, other).

Touch preparation smears performed at

and results

reported to the

M.D., Senior

Staff Pathologist

Gross Description

A. Brain, nonenhancing tumor, biopsy:

CONTAINER LABEL: nonenhancing brain tumor. FIXATIVE: None.

GENERAL: A 2 x 1.5 x 1 cm portion of pale gray-tan brain tissue, submitted fresh for intraoperative evaluation. The

specimen is serially sectioned, and representatives are utilized for cytological preparations.

SECTIONS: Entirely submitted in A1 - A3.

B. Brain, right insular tumor, excision biopsy:

CONTAINER LABEL: right insular tumor. FIXATIVE: None.

GENERAL: A 2.2 x 1.7 x 0.9 cm aggregate of multiple irregular portions of tan-gray brain tissue.

SECTIONS: Entirely submitted in B1 - B2.

Microscopic Description

The frozen section diagnosis is confirmed on the permanent sections.

IMMUNOHISTOCHEMISTRY: GFAP demonstrates dense gliofibrillogenesis by the neoplastic cells throughout the

tumor. Synaptophysin demonstrates infiltrative neoplastic cells at the periphery of solid tumor.

SPECIAL STAIN: Snook's reticulum stain demonstrates absence of reticulin fibers within the neoplasm.

ICD-9(s): 225.0 225.0 191.9

Billing Fee Code(s): A:

B:

LOH 1p19q:

MGMT:

Case Is (Initials)		

DATE: 9/13/13

Source: NCI Genomic Data Commons file 6cb94683-fc98-4236-8415-7f6a081980a6 (TCGA-06-A7TL.A492E3BF-5ABE-4D39-A40C-6028BB6DDBEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).